Somatic mutation profile of tumor specimen TCGA-QQ-A8VG-01A (aliquot TCGA-QQ-A8VG-01A-11D-A37C-09) from TCGA case TCGA-QQ-A8VG, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 52.9 years (19,304 days).
Specimen TCGA-QQ-A8VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e09156-e73c-4f2e-be6d-cf588fa1c45b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A8VG-10A (Blood Derived Normal), aliquot TCGA-QQ-A8VG-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbd6a88a-2b54-4f73-89ec-96bc78114d36

The open-access MAF lists 476 somatic variants for this specimen: 302 protein-altering or splice-affecting, 163 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 270, Silent 163, Nonsense Mutation 21, RNA 6, Splice Region 5, Frame Shift Del 2, 3'UTR 2, Intron 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.3451C>T p.R1151* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs868985556, COSV63289633; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs397507503, CM122798, COSV61006484, COSV61013714; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTPN11 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM043070, CM052358, COSV61008620; called by muse, mutect2, varscan2
- A4GALT | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50745856, COSV99966772; called by muse, mutect2, varscan2
- AAK1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV101117270; called by muse, mutect2, varscan2
- ABCA1 | c.5618G>A p.R1873K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs982161167, COSV101037637; called by muse, mutect2, varscan2
- ABCB5 | c.2489C>T p.S830F (on ENST00000404938 / NM_001163941.2; = p.S385F on NM_178559.6) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866781790, COSV51705583; called by muse, mutect2, varscan2
- ABCC12 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100253227; called by muse, mutect2, varscan2
- ABCC3 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99559809; called by muse, mutect2, varscan2
- ABCF3 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99491649; called by muse, mutect2, varscan2
- ABI3BP | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99426160, COSV99428564; called by muse, mutect2
- ABR | c.2206C>G p.R736G (on ENST00000302538 / NM_021962.5; = p.R699G on NM_001092.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.499); catalogued as COSV52142366, COSV52142610, COSV99348571; called by muse, mutect2, varscan2
- ACAN | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as COSV100719241; called by muse, mutect2, varscan2
- ACAP1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV99341981; called by muse, mutect2, varscan2
- ACTG2 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100609496; called by muse, mutect2, varscan2
- ADCY1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52031045; called by muse, varscan2
- ADGRF4 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as rs1380109055, COSV51950592, COSV99348973; called by muse, mutect2, varscan2
- ADGRL2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV54680746; called by muse, mutect2
- ADGRL4 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV66060039; called by muse, mutect2, varscan2
- ADGRV1 | c.11722G>A p.D3908N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as rs749544658, COSV101316185, COSV67979351; called by muse, mutect2, varscan2
- AFF2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV99666188; called by muse, mutect2, varscan2
- AGAP4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.041); catalogued as rs1417393854; called by muse, varscan2
- AKNAD1 | c.1245G>A p.L415= | Splice Region (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100645866; called by muse, mutect2, varscan2
- ANKRD30A | c.824G>A p.G275E (on ENST00000611781; = p.G219E on NM_052997.2) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs1455673314, COSV100653516; called by muse, mutect2, varscan2
- ARID3A | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs767204634, COSV99708533; called by muse, mutect2, varscan2
- ASTL | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100668444; called by muse, mutect2, varscan2
- ATG2B | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99952240; called by muse, mutect2, varscan2
- ATP2B2 | c.1364C>T p.S455L (on ENST00000352432; = p.S421L on NM_001683.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1198836153, COSV100660404; called by muse, mutect2, varscan2
- ATP5F1A | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.317); catalogued as rs1372292438, COSV99959158; called by muse, mutect2
- BAHD1 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.086); catalogued as COSV101346798; called by muse, mutect2, varscan2
- BEST2 | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99244297, COSV99244668; called by muse, mutect2, varscan2
- BHMT2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670295; called by muse, mutect2, varscan2
- BRINP1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV56301688, COSV99774364; called by muse, mutect2, varscan2
- BRINP1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.037); catalogued as COSV56296410, COSV56304407; called by muse, mutect2, varscan2
- BRINP3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.026); catalogued as COSV100818610; called by muse, mutect2, varscan2
- C11orf42 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs779693172, COSV99792493; called by muse, mutect2, varscan2
- C12orf43 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV99982997; called by muse, mutect2, varscan2
- C7 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764221802, COSV100496574; called by muse, mutect2, varscan2
- C8orf34 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV57410813; called by muse, mutect2, varscan2
- C9 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs867203884, COSV54678843; called by muse, mutect2, varscan2
- CA2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs143666045; called by muse, mutect2, varscan2
- CACNA1H | c.6833G>A p.G2278E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs1347149468, COSV99327074; called by muse, mutect2, varscan2
- CACNA1S | c.3986T>A p.L1329Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100755377; called by muse, mutect2, varscan2
- CALCRL | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as COSV101131039; called by muse, mutect2, varscan2
- CAPN13 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as rs373913163, COSV54429576; called by muse, mutect2, varscan2
- CBX8 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99485975; called by muse, mutect2, varscan2
- CCDC144A | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1567599472; called by muse, mutect2, varscan2
- CDH16 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234187; called by muse, mutect2, varscan2
- CDH9 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs967893158, COSV50300614, COSV99151258; called by muse, mutect2, varscan2
- CENPT | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV99535342; called by muse, mutect2, varscan2
- CFAP65 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99838452; called by muse, mutect2
- CGNL1 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849145; called by muse, mutect2
- CHAT | c.1455G>A p.W485* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV60327891; called by muse, mutect2, varscan2
- CHODL | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV100167083; called by muse, mutect2, varscan2
- CHRNA6 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99373417; called by muse, mutect2
- CILP | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as rs778069071, COSV99973939; called by muse, mutect2, varscan2
- CMKLR1 | c.938C>T p.P313L (on ENST00000312143 / NM_001142344.2; = p.P311L on NM_004072.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379612; called by muse, mutect2, varscan2
- CNTFR | c.1096A>C p.T366P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV100667625; called by muse, mutect2, varscan2
- CNTN6 | c.2097C>T p.V699= | Splice Region (SNP) | VAF 19/96 reads (20%) | catalogued as COSV63194884; called by muse, mutect2, varscan2
- COL11A1 | c.4384G>A p.G1462S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618023; called by muse, mutect2, varscan2
- COL15A1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs185912222, COSV66645618; called by muse, mutect2, varscan2
- COL16A1 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1457057294, COSV99595431; called by muse, mutect2, varscan2
- COL19A1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs767849294, COSV100507495; called by muse, mutect2, varscan2
- COL22A1 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs150603745; called by mutect2, varscan2
- COL4A5 | c.3304G>A p.D1102N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100089863; called by muse, mutect2, varscan2
- COL4A6 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873955; called by muse, mutect2, varscan2
- COL5A2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100880797; called by muse, mutect2, varscan2
- COLQ | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374783562; called by muse, mutect2, varscan2
- CPAMD8 | c.3896C>T p.A1299V (on ENST00000651564; = p.A1252V on NM_015692.5) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV101488600; called by muse, mutect2, varscan2
- CREBRF | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99756420; called by muse, mutect2, varscan2
- CUL7 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99539223; called by muse, mutect2, varscan2
- CUZD1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100158988; called by muse, mutect2, varscan2
- CYP1A2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs747544962, COSV100673943; called by muse, mutect2, varscan2
- CYP2C18 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53669658; called by muse, mutect2, varscan2
- CYP2C19 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.845); catalogued as rs1196078753, COSV64907829; called by muse, mutect2, varscan2
- CYP3A4 | c.1393C>T p.P465S (on ENST00000336411; = p.P434S on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100315924; called by muse, mutect2, varscan2
- DCAF4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1446161053, COSV100611172; called by muse, mutect2, varscan2
- DCC | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100503040; called by muse, mutect2, varscan2
- DLAT | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734998; called by muse, mutect2, varscan2
- DLGAP3 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99333173; called by muse, mutect2, varscan2
- DLL4 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1243523935, COSV51062304; called by muse, mutect2
- DMBT1 | c.5914G>A p.D1972N (on ENST00000338354 / NM_001377530.1; = p.D1215N on NM_004406.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.883); catalogued as rs778186760, COSV57543102; called by muse, mutect2, varscan2
- DMRT2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99426237; called by muse, mutect2, varscan2
- DMRTC2 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54185633, COSV99523465; called by muse, mutect2, varscan2
- DNAH10 | c.6535G>A p.G2179S (on ENST00000409039; = p.G2118S on NM_207437.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs919744942, COSV101292706; called by muse, mutect2, varscan2
- DNAH10 | c.8235G>A p.W2745* (on ENST00000409039; = p.W2684* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV101292708; called by muse, mutect2
- DNAH6 | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV52854737, COSV99408691; called by muse, mutect2, varscan2
- DNAH7 | c.7213G>A p.E2405K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV100417525; called by muse, mutect2, varscan2
- DOCK2 | c.5134G>C p.E1712Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.287); catalogued as COSV56958769, COSV99915365; called by mutect2, varscan2
- DOCK2 | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99915368; called by muse, mutect2, varscan2
- DSC3 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100844734; called by muse, mutect2, varscan2
- DSE | c.2844G>A p.W948* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs763226255, COSV100528799, COSV59061386; called by muse, mutect2, varscan2
- DYM | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as rs756877451, COSV53980097; called by muse, mutect2, varscan2
- EML5 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV100716175; called by muse, mutect2, varscan2
- EPHA2 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746635122, COSV100626280; called by muse, mutect2, varscan2
- ERBB4 | c.2239C>T p.P747S | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV53570028; called by muse, mutect2, varscan2
- ETNK2 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100916679; called by muse, mutect2, varscan2
- FADS1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99952548; called by muse, mutect2, varscan2
- FARP2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1172435178, COSV50877786; called by muse, mutect2, varscan2
- FAT1 | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV71673280; called by muse, mutect2, varscan2
- FCRL1 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs777673848, COSV100839900; called by muse, mutect2, varscan2
- FGFR4 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1370781803, COSV99450871; called by muse, mutect2
- FOXI1 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60388678; called by muse, mutect2
- FPR3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100200880; called by muse, mutect2, varscan2
- FSD2 | c.1872G>A p.W624* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV58009766, COSV58013057; called by muse, mutect2, varscan2
- FYCO1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99946245; called by muse, mutect2, varscan2
- GABRA6 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99195135; called by muse, mutect2, varscan2
- GBA3 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV101545570; called by muse, mutect2, varscan2
- GEMIN5 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99594308; called by muse, mutect2, varscan2
- GOLPH3 | c.719T>A p.I240N | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99417503; called by muse, mutect2, varscan2
- GON4L | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV99675732; called by muse, mutect2, varscan2
- GPAM | c.2293A>G p.R765G | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as COSV100788423; called by muse, mutect2, varscan2
- GRID2 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1229928761, COSV56220795; called by muse, mutect2, varscan2
- GRIK2 | c.716T>G p.L239* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100029337; called by muse, mutect2, varscan2
- GRM8 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.103); catalogued as rs148553836, COSV100286014; called by muse, varscan2
- GZMK | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764459042, COSV99141004; called by muse, mutect2, varscan2
- HAUS4 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99247146; called by muse, mutect2, varscan2
- HCFC1 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100129876; called by muse, mutect2, varscan2
- HHIPL1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779791168, COSV58090320; called by muse, mutect2, varscan2
- HLA-E | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.958); catalogued as COSV100931991; called by muse, mutect2, varscan2
- HNRNPM | c.1038G>A p.M346I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs140407642; called by muse, mutect2, varscan2
- HSP90AB1 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100807206; called by muse, mutect2, varscan2
- HVCN1 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1259966190, COSV99657460; called by muse, mutect2, varscan2
- IFNL2 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV59593422; called by muse, mutect2, varscan2
- IGSF22 | c.2466G>A p.W822* (on ENST00000319338; = p.W923* on NM_173588.4) | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99773868; called by muse, mutect2
- IGSF9 | c.2348C>T p.P783L (on ENST00000368094 / NM_001135050.2; = p.P767L on NM_020789.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100231347, COSV57422266; called by muse, mutect2, varscan2
- IL2RB | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.263); catalogued as COSV53425118, COSV53428613; called by muse, mutect2, varscan2
- INHBA | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99638370; called by muse, mutect2, varscan2
- IQCF2 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100291106; called by muse, mutect2
- ITGAX | c.705C>T p.V235= | Splice Region (SNP) | VAF 6/46 reads (13%) | catalogued as rs372032821, COSV51644200; called by muse, mutect2
- ITIH1 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99835624; called by muse, mutect2, varscan2
- KALRN | c.4304G>A p.G1435E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99567255; called by muse, mutect2, varscan2
- KCNH1 | c.2662G>A p.D888N (on ENST00000271751 / NM_172362.3; = p.D861N on NM_002238.4) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.27); catalogued as rs778733037, COSV99661422; called by muse, mutect2
- KCNRG | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs369440174, COSV100466468; called by muse, mutect2, varscan2
- KCNT2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1452776560, COSV54065701; called by muse, mutect2, varscan2
- KHSRP | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV101231248; called by muse, mutect2, varscan2
- KIAA0232 | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1315171150, COSV100301099; called by muse, mutect2
- KIAA1549 | c.3695G>A p.G1232E | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1433358181, COSV99651973; called by muse, mutect2
- KL | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101199199; called by muse, mutect2, varscan2
- KPNA2 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV100388886; called by muse, mutect2, varscan2
- KRT75 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs779265925, COSV99359631; called by muse, mutect2, varscan2
- KRT86 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs752211932, COSV53291952; called by muse, mutect2, varscan2
- KRTAP10-11 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100555457, COSV58178358; called by muse, mutect2, varscan2
- LAMA2 | c.4562G>A p.G1521E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370827; called by muse, mutect2, varscan2
- LGR6 | c.1622C>T p.P541L (on ENST00000367278 / NM_001017403.1; = p.P489L on NM_021636.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1260923333, COSV99707867; called by muse, mutect2, varscan2
- LIX1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV99172972; called by muse, mutect2, varscan2
- LOXL4 | c.276G>A p.E92= | Splice Region (SNP) | VAF 20/122 reads (16%) | catalogued as COSV99584212; called by muse, mutect2, varscan2
- LPA | c.4217G>A p.G1406E | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV60313757; called by muse, mutect2
- LRIG2 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100743699; called by muse, mutect2, varscan2
- LRP1B | c.6827A>G p.Y2276C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67226775; called by muse, mutect2, varscan2
- LRRFIP1 | c.829C>T p.P277S (on ENST00000392000 / NM_001137552.2; = p.P253S on NM_004735.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.73); catalogued as COSV99791260; called by muse, mutect2, varscan2
- LY6G6C | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.046); catalogued as COSV101009784; called by muse, mutect2, varscan2
- MAGEC1 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.996); catalogued as COSV53568554, COSV99596501; called by muse, mutect2, varscan2
- ME1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs780787550, COSV63839355; called by muse, mutect2, varscan2
- MEGF10 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99175649; called by muse, mutect2, varscan2
- MEX3B | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.063); catalogued as rs1314872207, COSV100314219, COSV100314281; called by muse, mutect2, varscan2
- MGAM | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101527746; called by muse, mutect2, varscan2
- MGAM | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs777169037, COSV72074491; called by muse, mutect2, varscan2
- MMP16 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV54161243; called by muse, mutect2, varscan2
- MTTP | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV99645571; called by muse, mutect2
- MUC16 | c.30629C>T p.S10210L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs1409544932, COSV101198522, COSV67442346; called by muse, mutect2, varscan2
- MUC2 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1384770554; called by muse, mutect2, varscan2
- MXRA5 | c.5935G>A p.A1979T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV99479191; called by muse, mutect2, varscan2
- MYH1 | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs141339850, COSV56845648, COSV56845695; called by muse, mutect2, varscan2
- MYH7B | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.784); catalogued as rs1307668352, COSV99483283; called by muse, mutect2, varscan2
- MYO15A | c.8590G>A p.E2864K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99234386; called by muse, mutect2
- MYO18A | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs773322706, COSV100572726; called by muse, mutect2, varscan2
- MYO7B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67346492; called by muse, mutect2, varscan2
- NDRG4 | c.921G>A p.M307I (on ENST00000570248 / NM_001378344.1; = p.M326I on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs1173006919, COSV99262542; called by muse, mutect2, varscan2
- NFAT5 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as COSV100591217; called by muse, mutect2
- NID1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.302); catalogued as COSV51629610, COSV99053773; called by muse, mutect2, varscan2
- NLRC3 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100073391; called by muse, mutect2, varscan2
- NLRP6 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1298758520, COSV56459880; called by muse, mutect2, varscan2
- NOS2 | c.1002C>T p.P334= | Splice Region (SNP) | VAF 15/66 reads (23%) | catalogued as COSV100569890; called by muse, mutect2, varscan2
- OGDHL | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs780602132, COSV100934515; called by muse, mutect2, varscan2
- OPALIN | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs770990264, COSV100959684, COSV100959688; called by muse, mutect2, varscan2
- OR10W1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.802); catalogued as COSV67720524, COSV67720616; called by muse, mutect2, varscan2
- OR14K1 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV51721143, COSV99315167; called by muse, mutect2, varscan2
- OR52L1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV59987391, COSV59987504; called by muse, mutect2, varscan2
- OR5B2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.139); catalogued as rs1261650990, COSV100222975, COSV56908068; called by muse, mutect2, varscan2
- OR5K4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs902873759, COSV61583677; called by muse, mutect2, varscan2
- OR6C3 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs771309358, COSV101110388; called by muse, mutect2, varscan2
- OSGEP | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99248219; called by muse, mutect2, varscan2
- OTOF | c.4960+1G>A p.X1654_splice (on ENST00000272371 / NM_194248.3; = p.X887_splice on NM_004802.4) | Splice Site (SNP) | VAF 27/150 reads (18%) | catalogued as COSV55511180; called by muse, mutect2, varscan2
- OXGR1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037113; called by muse, mutect2, varscan2
- P3H2 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV60022259; called by muse, mutect2, varscan2
- PCDHA4 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.113); catalogued as COSV63540288; called by muse, mutect2, varscan2
- PCDHA6 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100972421; called by muse, mutect2, varscan2
- PCDHA8 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs782581098, COSV100971033; called by muse, mutect2, varscan2
- PCDHB13 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782298061, COSV99507831; called by muse, mutect2, varscan2
- PCDHB2 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as COSV99523570; called by muse, mutect2, varscan2
- PCLO | c.10856C>T p.S3619F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945443608, COSV61627938; called by muse, mutect2, varscan2
- PDE6C | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV63270851, COSV63273646; called by muse, mutect2, varscan2
- PDGFB | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs146204796; called by muse, mutect2, varscan2
- PDHB | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100240152, COSV100240255; called by muse, mutect2, varscan2
- PENK | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV59243187; called by muse, mutect2, varscan2
- PGAP1 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100698358; called by muse, mutect2, varscan2
- PI16 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1442694917, COSV101010209; called by muse, mutect2, varscan2
- PIK3C2G | c.3710C>T p.S1237F (on ENST00000676171; = p.S1196F on NM_004570.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.591); catalogued as rs950782237, COSV56840543; called by muse, mutect2, varscan2
- PLCZ1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs867053530, COSV99856977; called by muse, mutect2, varscan2
- PLEKHA6 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99692756; called by muse, mutect2, varscan2
- PRAG1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs566296772, COSV100422798; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- PRKCH | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100273768; called by muse, mutect2, varscan2
- PRKCQ | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99577844; called by muse, mutect2, varscan2
- PSG5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV61653914; called by muse, mutect2, varscan2
- PTBP3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99270420; called by muse, mutect2, varscan2
- PTPRB | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs267603653, COSV99718926; called by muse, mutect2, varscan2
- PTPRS | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV99512382; called by muse, mutect2, varscan2
- PTX4 | c.1199C>T p.S400F (on ENST00000447419 / NM_001328608.2; = p.S395F on NM_001013658.1) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99560780; called by muse, mutect2, varscan2
- RAB11FIP4 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100365780; called by muse, mutect2, varscan2
- RAB4A | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.438); catalogued as COSV64207279, COSV64207717; called by muse, mutect2, varscan2
- RBFOX1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101384631; called by muse, mutect2, varscan2
- REG3G | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs557732692, COSV55451253; called by muse, mutect2, varscan2
- RELA | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100425939; called by muse, mutect2, varscan2
- REXO1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs147534740; called by muse, mutect2, varscan2
- RFX6 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100264287, COSV60584466; called by muse, mutect2, varscan2
- RGS7 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58542153; called by muse, mutect2, varscan2
- RIMS2 | c.4225C>T p.R1409C (on ENST00000666250 / NM_001348490.2; = p.R980C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539179964, COSV51652584; called by muse, mutect2, varscan2
- RNASEL | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs777458937, COSV62378236; called by muse, mutect2, varscan2
- RPL5 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100240497; called by muse, mutect2, varscan2
- RPN2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.324); catalogued as rs1204431067, COSV99412047; called by muse, mutect2, varscan2
- RSF1 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV57839418; called by muse, mutect2, varscan2
- RSPH6A | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV55572034; called by muse, mutect2, varscan2
- S1PR1 | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100541677; called by muse, mutect2, varscan2
- SALL1 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772476680, COSV51753884; called by muse, mutect2, varscan2
- SCN10A | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV101479538; called by muse, mutect2
- SCN2A | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV99333471; called by muse, mutect2, varscan2
- SCN3A | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99328498; called by muse, mutect2
- SCP2D1 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs575292008, COSV99602211; called by muse, mutect2, varscan2
- SDK1 | c.6604G>C p.A2202P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV101269843, COSV67365885; called by muse, mutect2, varscan2
- SEC31B | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1429635314, COSV100944915; called by muse, mutect2, varscan2
- SEPTIN1 | c.658G>A p.D220N (on ENST00000321367; = p.D173N on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100363163; called by muse, mutect2, varscan2
- SH2D4B | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100214251; called by muse, mutect2, varscan2
- SHANK1 | c.4394A>T p.E1465V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV99522041; called by muse, mutect2, varscan2
- SIGLEC7 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs759671422, COSV58315054; called by muse, mutect2, varscan2
- SLC13A1 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99521467; called by muse, mutect2, varscan2
- SLC13A1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1563323923, COSV52008686; called by muse, mutect2, varscan2
- SLC17A6 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs773314692, COSV54140333; called by mutect2, varscan2
- SLC38A11 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs747625648, COSV100367047; called by muse, mutect2, varscan2
- SLC6A5 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100117149, COSV54230652; called by muse, mutect2, varscan2
- SLN | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100019532; called by muse, mutect2, varscan2
- SMPD3 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99546048; called by muse, mutect2, varscan2
- SP1 | c.1763G>A p.S588N (on ENST00000327443 / NM_138473.3; = p.S581N on NM_003109.1) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV100540858; called by muse, mutect2, varscan2
- SP140 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1200048890, COSV100614074; called by muse, mutect2, varscan2
- SPATA17 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100861231; called by muse, mutect2, varscan2
- SPATA31A6 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs559633705, COSV100253774; called by muse, mutect2, varscan2
- SPEN | c.7556C>T p.P2519L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101005595; called by muse, mutect2, varscan2
- SPTA1 | c.4691C>T p.S1564F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100935561, COSV63752177; called by muse, mutect2, varscan2
- SRSF1 | c.68T>C p.L23S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365482; called by muse, mutect2, varscan2
- SRSF1 | c.67T>A p.L23I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365486; called by muse, mutect2, varscan2
- ST6GAL2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | PolyPhen benign (0.135); catalogued as COSV64529701; called by muse, mutect2, varscan2
- STK33 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs779889141, COSV100174515; called by muse, mutect2, varscan2
- SYNE1 | c.6405G>A p.M2135I (on ENST00000367255 / NM_182961.4; = p.M2142I on NM_033071.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV99578361, COSV99578987; called by muse, mutect2, varscan2
- SYNGAP1 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99538197; called by muse, mutect2, varscan2
- TACC2 | c.7877C>T p.P2626L (on ENST00000334433; = p.P704L on NM_006997.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99587721; called by muse, mutect2
- TACC2 | c.8398G>A p.E2800K (on ENST00000334433; = p.E878K on NM_006997.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs762669751, COSV53277104; called by muse, mutect2, varscan2
- TCF12 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99978929; called by muse, mutect2, varscan2
- TCF4 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100610843; called by muse, mutect2
- TEC | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101202686; called by muse, mutect2, varscan2
- TJP3 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs144472063; called by muse, mutect2, varscan2
- TLR2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99472542; called by muse, mutect2, varscan2
- TMC7 | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100432820; called by muse, mutect2, varscan2
- TMEM119 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV101219552; called by muse, mutect2, varscan2
- TMIE | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs1185865315, COSV100167973; called by muse, varscan2
- TNFRSF8 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.427); catalogued as COSV99821914; called by muse, mutect2, varscan2
- TNNT3 | c.529G>A p.G177S (on ENST00000397301 / NM_001367846.1; = p.G166S on NM_006757.4) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99548759; called by muse, mutect2, varscan2
- TNPO1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100473995; called by muse, mutect2, varscan2
- TNRC18 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1212758148, COSV101259525; called by muse, mutect2
- TRPC4AP | c.860A>C p.N287T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99328892, COSV99329090; called by muse, mutect2, varscan2
- TRPC6 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723758; called by muse, mutect2, varscan2
- TSEN2 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99539399; called by muse, mutect2, varscan2
- TTN | c.78799G>A p.E26267K (on ENST00000591111; = p.E18843K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | PolyPhen benign (0.167); catalogued as COSV59933576; called by muse, mutect2, varscan2
- TTN | c.18598G>A p.D6200N (on ENST00000591111; = p.D5273N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | PolyPhen probably damaging (0.964); catalogued as COSV100629634; called by muse, mutect2, varscan2
- TTN | c.9463G>A p.E3155K (on ENST00000591111; = p.E3109K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | PolyPhen benign (0.053); catalogued as COSV100629641; called by muse, mutect2
- ULK1 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100417271; called by muse, mutect2, varscan2
- UNC5A | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 20/125 reads (16%) | catalogued as COSV56166179; called by muse, mutect2, varscan2
- VN1R2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV59038850; called by muse, mutect2, varscan2
- WDR36 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747445944, COSV101551010; called by muse, mutect2, varscan2
- WEE2 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101187688; called by muse, mutect2, varscan2
- YLPM1 | c.4069C>T p.R1357* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs1358992706, COSV53108618; called by muse, mutect2, varscan2
- ZBBX | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100284953; called by muse, mutect2, varscan2
- ZER1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as rs771021525, COSV99402408; called by muse, mutect2, varscan2
- ZFX | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs748417793, COSV58447078; called by muse, mutect2, varscan2
- ZNF160 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as rs757182149, COSV62000244; called by muse, mutect2, varscan2
- ZNF331 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.839); catalogued as rs1386396710, COSV99467938; called by muse, mutect2, varscan2
- ZNF335 | c.2578C>T p.Q860* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100533375; called by muse, mutect2, varscan2
- ZNF358 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1413618079, COSV99900872; called by muse, mutect2, varscan2
- ZNF536 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1474387763, COSV62824727; called by muse, mutect2, varscan2
- ZNF560 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.713); catalogued as COSV100039031; called by muse, mutect2, varscan2
- ZNF684 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV101016130; called by muse, mutect2
- ZNF687 | c.3170C>T p.S1057F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs938678836, COSV99650152; called by muse, mutect2, varscan2
- ZNF804A | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); catalogued as rs147922206, COSV56435272, COSV56461319; called by muse, mutect2, varscan2
- ZNF804A | c.2990G>A p.G997E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56451302; called by muse, mutect2, varscan2
- GPR179 | c.429A>C p.R143S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- IGHV4-28 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR2L13 | c.861del p.I288Sfs*4 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- PIN1 | c.214del p.S72Pfs*17 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | called by mutect2, pindel*, varscan2
- PPWD1 | c.679dup p.T227Nfs*16 | Frame Shift Ins (INS) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 29/373 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC12A7 | c.1148_1150del p.Y383_A384delinsS | In Frame Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel*, varscan2*
- A2M | c.4008G>A p.K1336= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs762605452, COSV100589017, COSV100589072; called by muse, mutect2, varscan2
- ABTB2 | c.2610C>T p.F870= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100132136; called by muse, mutect2, varscan2
- ADCY7 | c.522C>T p.V174= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs752519334, COSV99576371; called by muse, mutect2, varscan2
- AK8 | c.1020G>A p.L340= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV100050540; called by muse, mutect2, varscan2
- AKR1C3 | c.729C>T p.A243= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs782175496, COSV101003169; called by muse, mutect2, varscan2
- AMN | c.225G>A p.G75= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100141585; called by muse, mutect2, varscan2
- ANKS1A | c.2955C>T p.I985= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100832821; called by muse, mutect2, varscan2
- AQP12B | c.195C>T p.F65= (on ENST00000621682; = p.F77= on NM_001102467.2) | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV101315931; called by muse, mutect2, varscan2
- ASH1L | c.2322C>T p.F774= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100853579; called by muse, mutect2, varscan2
- ASPH | c.2259C>T p.R753= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100370676; called by muse, mutect2, varscan2
- ASS1 | c.1041G>A p.G347= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1387711366, COSV100752824; called by muse, mutect2, varscan2
- ASTN1 | c.2371C>T p.L791= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99923052; called by muse, mutect2, varscan2
- ASXL3 | c.4617C>T p.F1539= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99324555; called by muse, mutect2, varscan2
- ATM | c.4173C>T p.A1391= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as rs1060504284, COSV99591869; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATR | c.7029C>T p.S2343= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100638472, COSV100638581; called by muse, mutect2, varscan2
- C15orf39 | c.1059C>T p.P353= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs769918034, COSV62296714; called by muse, mutect2, varscan2
- C16orf89 | c.231G>A p.E77= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs925765691, COSV100280988; called by muse, mutect2
- C1S | c.48G>A p.E16= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1487179520, COSV100196540; called by muse, mutect2, varscan2
- C1orf87 | c.1377C>T p.F459= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs368478097; called by muse, mutect2, varscan2
- C22orf42 | c.348G>A p.V116= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV101173378; called by muse, mutect2, varscan2
- C2orf76 | c.117C>T p.I39= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs774261753, COSV58347555; called by muse, mutect2, varscan2
- C6 | c.981G>A p.T327= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs146851023; called by muse, mutect2, varscan2
- C6orf89 | c.678C>T p.F226= (on ENST00000373685; = p.F233= on NM_152734.4) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs776924576, COSV100769772; called by muse, mutect2, varscan2
- CACNA1D | c.2931C>T p.I977= (on ENST00000350061 / NM_001128840.3; = p.I997= on NM_000720.4) | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1016504102, COSV99859992; called by muse, mutect2, varscan2
- CACNA1G | c.5232G>A p.G1744= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100662540; called by muse, mutect2, varscan2
- CCDC114 | c.1185C>T p.L395= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs267605561, COSV100196314, COSV100197083; called by muse, mutect2, varscan2
- CCDC144A | c.60C>T p.V20= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV100502190; called by muse, mutect2, varscan2
- CCDC171 | c.262C>T p.L88= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs796189766, COSV99901954; called by muse, mutect2, varscan2
- CDCP1 | c.576G>A p.V192= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99944300; called by muse, mutect2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- CMKLR1 | c.939C>T p.P313= (on ENST00000312143 / NM_001142344.2; = p.P311= on NM_004072.3) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100379610, COSV56441520; called by muse, mutect2, varscan2
- COL6A3 | c.4014G>A p.Q1338= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99801399; called by muse, mutect2, varscan2
- CREB3L1 | c.804G>A p.R268= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99915303; called by muse, mutect2, varscan2
- CSMD1 | c.6753C>T p.F2251= (on ENST00000520002; = p.F2250= on NM_033225.6) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs752350985, COSV100153589, COSV59290346; called by muse, mutect2, varscan2
- CSMD2 | c.1839G>A p.E613= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99595199; called by muse, mutect2, varscan2
- CSNK1G2 | c.1209C>T p.F403= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99730237; called by muse, mutect2, varscan2
- CST1 | c.423C>T p.S141= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100494401, COSV59055529; called by muse, mutect2, varscan2
- CTNND2 | c.2832G>A p.G944= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV100480998; called by muse, mutect2, varscan2
- DAB1 | c.1020C>A p.L340= (on ENST00000371231; = p.L307= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100976636, COSV64696262; called by muse, mutect2
- DCAF5 | c.2001C>T p.L667= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100432831; called by muse, mutect2, varscan2
- DCC | c.2259C>T p.I753= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs367899755; called by muse, mutect2, varscan2
- DMRT3 | c.603G>A p.E201= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99506079; called by muse, mutect2, varscan2
- DMTN | c.738C>T p.S246= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99742184; called by muse, varscan2
- DOCK2 | c.5313C>T p.I1771= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56942769; called by muse, mutect2, varscan2
- EFCAB5 | c.2986C>T p.L996= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100300740; called by muse, mutect2, varscan2
- EFCAB6 | c.1179C>T p.I393= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99414400; called by muse, mutect2, varscan2
- ELL | c.246C>T p.S82= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99443750; called by muse, mutect2, varscan2
- ELN | c.1242C>T p.I414= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV99333130; called by muse, mutect2, varscan2
- EPHA2 | c.2640C>T p.S880= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100626048; called by muse, mutect2
- ESAM | c.570G>A p.Q190= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99632129; called by muse, mutect2, varscan2
- FAM71B | c.1623C>T p.L541= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV57231371; called by muse, mutect2
- FAT4 | c.11028C>T p.S3676= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100630152; called by muse, mutect2, varscan2
- FBLN5 | c.195G>A p.G65= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV99969943; called by muse, mutect2, varscan2
- FCRL2 | c.345C>T p.S115= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV63833348; called by muse, mutect2
- FLNA | c.5124C>T p.F1708= (on ENST00000369850 / NM_001110556.2; = p.F1700= on NM_001456.3) | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs368399445, COSV100775239; ClinVar: likely benign; called by muse, mutect2, varscan2
- GBP2 | c.708C>T p.F236= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs1319474106, COSV100975432; called by muse, mutect2, varscan2
- GCM2 | c.267G>A p.Q89= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV101069621; called by muse, mutect2
- GIMAP6 | c.141G>A p.G47= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs138777121, COSV61032937; called by muse, mutect2
- GM2A | c.204C>T p.V68= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100852052; called by muse, mutect2, varscan2
- GMPS | c.1575C>T p.S525= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99903397; called by muse, mutect2, varscan2
- GPRIN1 | c.1380C>T p.S460= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99992180; called by muse, mutect2
- GRIK1 | c.1710C>T p.F570= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100517928; called by muse, mutect2
- GRIN2B | c.819C>T p.F273= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101663160; called by muse, mutect2, varscan2
- GRIN2C | c.3630A>G p.V1210= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99501443; called by muse, mutect2
- GRK7 | c.660G>A p.K220= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99380257; called by muse, mutect2, varscan2
- HHIPL1 | c.327G>A p.G109= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100415401; called by muse, mutect2, varscan2
- IGHV5-51 | c.120C>T p.S40= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as rs556197041; called by muse, mutect2, varscan2
- INF2 | c.3351C>T p.S1117= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99384364; called by muse, mutect2, varscan2
- IQCE | c.1014G>A p.R338= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs776630386, COSV100383641; called by muse, mutect2, varscan2
- IRF6 | c.1383C>T p.P461= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV99671230; called by muse, mutect2, varscan2
- IRF6 | c.1296C>T p.I432= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs778870225, CD133967, COSV54214889, COSV54215255; called by muse, mutect2, varscan2
- ITGA11 | c.2703G>A p.R901= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs764292180, COSV100242203; called by muse, mutect2, varscan2
- ITIH5 | c.405G>A p.E135= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs749252937, COSV56914239, COSV56917741; called by muse, mutect2, varscan2
- JAZF1 | c.351C>T p.T117= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99387335; called by muse, mutect2, varscan2
- KCNJ12 | c.36C>T p.I12= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs567413846, COSV59164690, COSV59176050; called by muse, mutect2
- KCNK5 | c.979C>T p.L327= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100851935; called by muse, mutect2, varscan2
- KCNMB4 | c.630T>C p.S210= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99253426; called by muse, mutect2, varscan2
- KCNV1 | c.399C>T p.F133= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV99819233; called by muse, mutect2
- KEL | c.273C>T p.A91= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100787014; called by muse, mutect2, varscan2
- KIR2DL4 | c.681C>G p.T227= (on ENST00000396284; = p.T188= on NM_001080770.2) | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- KIT | c.1278C>T p.L426= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV99855308; called by muse, mutect2, varscan2
- KRT33A | c.673C>T p.L225= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV99145012; called by muse, mutect2, varscan2
- LAMC1 | c.1677C>T p.F559= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs764632517, COSV99280437; called by muse, mutect2, varscan2
- LARP1 | c.2481C>T p.P827= (on ENST00000518297 / NM_033551.3; = p.P750= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100304092; called by muse, mutect2, varscan2
- LMX1A | c.906C>T p.I302= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs267598145, COSV54219392; called by muse, mutect2, varscan2
- LRRC3 | c.510C>T p.I170= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs755557165, COSV99381845; called by muse, mutect2, varscan2
- MORC1 | c.51C>T p.F17= | Silent (SNP) | VAF 32/201 reads (16%) | catalogued as rs1324985399, COSV51714699; called by muse, mutect2, varscan2
- MPPED1 | c.357C>T p.F119= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs769583180, COSV100501339; called by muse, mutect2, varscan2
- MROH8 | c.1860G>A p.E620= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs760737208, COSV99457917; called by muse, mutect2, varscan2
- MXRA5 | c.933C>T p.F311= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99479194; called by muse, mutect2, varscan2
- MYH7 | c.1119G>A p.A373= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs572672362, COSV62524712; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- MYOG | c.180C>T p.H60= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1359491318, COSV99614063; called by muse, mutect2, varscan2
- NCF1 | c.624C>T p.S208= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99194260; called by muse, mutect2, varscan2
- NCF4 | c.876G>A p.G292= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99957545; called by muse, mutect2, varscan2
- NCSTN | c.1851C>T p.L617= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99667619; called by muse, mutect2, varscan2
- NELL2 | c.1953G>A p.Q651= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100420801; called by muse, mutect2, varscan2
- NLRP2 | c.2643G>A p.G881= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV54759531; called by muse, mutect2, varscan2
- NOX4 | c.381C>T p.A127= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99631871; called by muse, mutect2, varscan2
- NXF1 | c.885C>T p.I295= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs144471031; called by muse, mutect2, varscan2
- OBSCN | c.16749C>T p.S5583= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs757298537, COSV99484135; called by muse, mutect2, varscan2
- OR10K1 | c.36C>T p.F12= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs200159566, COSV56872294, COSV56872710; called by muse, mutect2, varscan2
- OR2A14 | c.487C>T p.L163= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV101376497; called by muse, mutect2, varscan2
- OR2C1 | c.471G>A p.V157= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV100515029; called by muse, mutect2, varscan2
- OR4C15 | c.342C>T p.F114= (on ENST00000314644; = p.F60= on NM_001001920.2) | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100115384, COSV58953348; called by muse, mutect2, varscan2
- OR4D9 | c.753C>T p.F251= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as rs771977144, COSV61434214; called by muse, mutect2, varscan2
- OR4X2 | c.198C>T p.S66= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100183220, COSV100183343; called by muse, mutect2, varscan2
- OR51A2 | c.558C>T p.V186= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100985092; called by muse, mutect2, varscan2
- OR5D14 | c.384C>T p.I128= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100162608; called by muse, mutect2, varscan2
- OR8K5 | c.339C>T p.F113= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100537291; called by muse, mutect2, varscan2
- PADI2 | c.390G>A p.V130= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100971084; called by muse, mutect2, varscan2
- PASK | c.693C>T p.V231= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99300216; called by muse, mutect2, varscan2
- PCDHA1 | c.63C>T p.L21= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV65377305; called by muse, mutect2, varscan2
- PCDHAC2 | c.1893C>T p.D631= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99162121; called by muse, mutect2, varscan2
- PDGFA | c.291G>A p.K97= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100627270; called by muse, mutect2, varscan2
- PENK | c.714C>T p.A238= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs746841463, COSV59243004; called by muse, mutect2, varscan2
- PHF8 | c.2988C>T p.A996= (on ENST00000357988 / NM_001184896.1; = p.A960= on NM_015107.3) | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100154844; called by muse, mutect2, varscan2
- PLCB4 | c.1218C>T p.L406= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99596928; called by muse, mutect2, varscan2
- POU3F2 | c.1065G>A p.R355= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100099485; called by muse, mutect2, varscan2
- PRAM1 | c.1470C>T p.F490= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV99725862; called by muse, mutect2, varscan2
- PTPRU | c.2274C>T p.V758= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100113706; called by muse, mutect2, varscan2
- PUF60 | c.198C>T p.A66= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100513350; called by muse, mutect2, varscan2
- RAB31 | c.312G>A p.L104= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs996905734, COSV101444158; called by muse, mutect2
- RASL11A | c.432C>T p.I144= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs149565737, COSV99611165; called by muse, mutect2, varscan2
- RELN | c.1416G>A p.G472= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59020253; called by muse, mutect2, varscan2
- RIOK2 | c.1188C>T p.F396= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99300046; called by muse, mutect2, varscan2
- RNFT2 | c.861C>T p.I287= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99985565; called by muse, mutect2, varscan2
- RPRD2 | c.2853C>T p.T951= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs951524978, COSV100955367; called by muse, mutect2, varscan2
- RPS5 | c.276C>T p.I92= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs61731810, COSV52190691; called by muse, mutect2, varscan2
- SCN10A | c.2049C>T p.A683= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101479537; called by muse, mutect2
- SCN11A | c.2310C>T p.I770= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs773782966, COSV100182542; called by muse, mutect2, varscan2
- SCNM1 | c.177G>C p.L59= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99766202; called by muse, mutect2
- SDC2 | c.436C>T p.L146= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100144016; called by muse, mutect2, varscan2
- SEC14L4 | c.843G>A p.T281= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs760802294, COSV55399798; called by muse, mutect2
- SEL1L3 | c.1572G>A p.R524= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99341257; called by muse, mutect2, varscan2
- SH2D5 | c.876G>A p.T292= (on ENST00000444387 / NM_001103161.2; = p.T208= on NM_001103160.2) | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs759976133, COSV100903900; called by muse, mutect2, varscan2
- SHISA3 | c.330C>T p.I110= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100069930; called by muse, mutect2, varscan2
- SHKBP1 | c.1227C>T p.I409= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1568392991, COSV52542930; called by mutect2, varscan2
- SIRPB2 | c.297C>T p.I99= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100708635, COSV63123566; called by muse, mutect2, varscan2
- SLC10A6 | c.1101C>T p.L367= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs569333477, COSV99907393; called by muse, mutect2, varscan2
- SLC13A2 | c.87C>T p.I29= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs371984598; called by mutect2, varscan2
- SLC26A9 | c.1026C>T p.I342= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs530666216, COSV100536623; called by muse, mutect2, varscan2
- SLC34A1 | c.846C>T p.D282= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1050476708, COSV60996150; called by muse, mutect2, varscan2
- SPTBN1 | c.471C>T p.F157= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100443394; called by muse, mutect2, varscan2
- SYT10 | c.1092G>A p.L364= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1268186959, COSV99951987; called by muse, mutect2, varscan2
- SYT9 | c.435G>A p.Q145= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1301288877, COSV100609184; called by muse, mutect2, varscan2
- TACC2 | c.3771C>T p.S1257= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100553842; called by muse, mutect2, varscan2
- TACC2 | c.4248C>T p.F1416= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs186111089, COSV100553522; called by muse, mutect2, varscan2
- TARS3 | c.1752C>T p.F584= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs1055951057, COSV60108139; called by muse, mutect2, varscan2
- TAS2R38 | c.198C>T p.F66= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV101516478, COSV71885666; called by muse, mutect2, varscan2
- TMCO6 | c.537G>A p.E179= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- TRGC1 | c.114C>T p.F38= | Silent (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- TRIOBP | c.2904C>T p.T968= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100731117; called by muse, mutect2, varscan2
- TSPAN10 | c.484C>T p.L162= (on ENST00000574882 / NM_001290212.1; = p.L124= on NM_031945.4) | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as rs1269877831, COSV100148665; called by muse, mutect2, varscan2
- TTN | c.17499G>A p.Q5833= (on ENST00000591111; = p.Q4906= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100629637; called by muse, mutect2
- TUBB | c.1203G>A p.E401= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100013487; called by muse, mutect2, varscan2
- UTP6 | c.1242C>T p.I414= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs748597148, COSV99912131; called by muse, mutect2, varscan2
- WDR72 | c.1425G>A p.S475= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs771064286, COSV64742226; called by muse, mutect2, varscan2
- ZBTB32 | c.1182C>G p.V394= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV52889470, COSV99386264; called by mutect2, varscan2
- ZDHHC23 | c.942C>T p.T314= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100362252; called by muse, mutect2, varscan2
- ZMYM3 | c.3783C>T p.V1261= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100078387; called by muse, mutect2, varscan2
- ZNF628 | c.1557C>T p.F519= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs551631262, COSV99220280; called by muse, mutect2, varscan2
- ZRANB3 | c.2460C>T p.I820= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99924712; called by muse, mutect2, varscan2
- ZSCAN18 | c.1164C>T p.S388= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs754502510, COSV53734205; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663559 C>T | 3'Flank (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- AL163540.1 | n.45G>A | RNA (SNP) | VAF 29/432 reads (7%) | called by muse, mutect2
- BTN2A3P | n.1117C>T | RNA (SNP) | VAF 11/58 reads (19%) | catalogued as rs1561855597; called by muse, mutect2, varscan2
- DCHS2 | n.8336G>A | RNA (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100601244; called by muse, mutect2, varscan2
- FGFR3 | c.*300C>T | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as COSV53421387; called by muse, varscan2
- H2AC17 | c.*2G>A | 3'UTR (SNP) | VAF 18/140 reads (13%) | catalogued as rs1378880608; called by muse, mutect2, varscan2
- HELLPAR | n.204945C>T | RNA (SNP) | VAF 11/49 reads (22%) | catalogued as rs769499253, COSV100513721; called by muse, mutect2, varscan2
- MIR521-1 | n.46A>T | RNA (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr17:18607962 C>A | 5'Flank (SNP) | VAF 37/263 reads (14%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2411G>A | Intron (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99484139; called by muse, mutect2, varscan2
- SH2D6 | n.283C>T | RNA (SNP) | VAF 17/85 reads (20%) | catalogued as rs752478609, COSV100442598; called by muse, mutect2, varscan2
